Somatic mutation profile of tumor specimen TCGA-KK-A6DY-01A (aliquot TCGA-KK-A6DY-01A-12D-A30X-08) from TCGA case TCGA-KK-A6DY, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 50.4 years (18,420 days).
Specimen TCGA-KK-A6DY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b50176c-5dac-46f7-8cb2-70f73ddb58c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A6DY-11A (Solid Tissue Normal), aliquot TCGA-KK-A6DY-11A-11D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0f58ef2-ea51-4847-8b9e-9bbde10c1877

The open-access MAF lists 28 somatic variants for this specimen: 24 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 19, Silent 4, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADCY8 | c.2359G>A p.V787I | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.029); catalogued as rs747001489, COSV53917026; called by muse, mutect2, varscan2
- BPNT1 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs757240318, COSV59040651; called by mutect2, varscan2
- CEACAM7 | c.593A>G p.N198S | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV50073699; called by muse, mutect2
- COL5A1 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.805); catalogued as rs375762619; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A2 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65607798; called by muse, mutect2, varscan2
- CTNNB1 | c.1025G>A p.R342K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV62708767; called by muse, mutect2, varscan2
- DDN | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.023); catalogued as rs1471038858, COSV60293570; called by muse, mutect2, varscan2
- DPRX | c.119A>G p.Y40C | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64949801; called by muse, mutect2, varscan2
- DUOX2 | c.1642A>G p.I548V | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV66533151; called by muse, mutect2, varscan2
- FGFRL1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.24); catalogued as rs776843445, COSV53258430; called by muse, mutect2, varscan2
- FLT3 | c.1942+1G>C p.X648_splice | Splice Site (SNP) | VAF 29/142 reads (20%) | catalogued as rs909269674, COSV54061318; called by muse, mutect2, varscan2
- GPR87 | c.61C>A p.H21N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV53463817; called by muse, mutect2, varscan2
- MYO18B | c.5240G>A p.R1747H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.788); catalogued as rs895114905, COSV59141226; called by muse, mutect2
- NRXN1 | c.1954del p.Q652Kfs*17 | Frame Shift Del (DEL) | VAF 30/322 reads (9%) | catalogued as COSV58483745; called by mutect2, pindel
- PCDHB12 | c.1327G>A p.D443N | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782254141, COSV53395113, COSV53400333; called by muse, mutect2, varscan2
- PLEKHA5 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 28/124 reads (23%) | catalogued as COSV54706265; called by muse, mutect2, varscan2
- PRKD1 | c.2005A>G p.M669V | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs1314441475, COSV59577140; called by muse, mutect2
- SFMBT1 | c.2575G>A p.A859T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56255576; called by muse, mutect2, varscan2
- STIL | c.957T>A p.C319* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV54551889; called by muse, mutect2, varscan2
- TRIP4 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV56031985; called by muse, mutect2
- USP26 | c.2302C>A p.H768N | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.568); catalogued as COSV100896506, COSV63709166; called by muse, mutect2, varscan2
- ZNF623 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV71697273; called by muse, mutect2, varscan2
- CHD1L | c.32del p.G11Afs*31 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- CSMD1 | c.8607C>T p.A2869= (on ENST00000520002; = p.A2868= on NM_033225.6) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs779219870, COSV59338330; called by mutect2, varscan2
- MOCS1 | c.1068G>T p.G356= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV51365478; called by muse, mutect2, varscan2
- PIK3R3 | c.684G>A p.E228= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as rs1320183885, COSV53109340; called by muse, mutect2, varscan2
- SH3D19 | c.2190G>A p.P730= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs747615999, COSV58791974; called by muse, mutect2
